Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BX, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BX-01A (Primary Tumor).

HPV Discrepancy		☒
		lw 10/15/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy.

105-0-3

TUMOR SITE:

Isthmus, Left lobe.

carcinoma, papillary, thyroid 8260/3

Site thyroid, NOS C73.9

lw
10/15/11

HISTOLOGIC TYPE:

Papillary carcinoma.

TUMOR SIZE:

Greatest dimension 5.0 cm.

FOCALITY:

Unifocal.

LYMPH NODES:

One (1) of four (4) lymph nodes, positive for carcinoma (tumor cells highlighted by AE1/3 immunostain).

EXTENT OF INVASION (7th Edition AJCC):

PRIMARY TUMOR:

pT3: Tumor > 4 cm, with extrathyroidal extension.

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to one lymph node (immediately adjacent to thyroid).

MARGINS:

Tumor extends close to resections margins. Distance of invasive carcinoma from nearest margin: less than 1.0 mm. Specify margin: Anterior and posterior.

VENOUS/LYMPHATIC INVASION:

Present: multifocal intrathyroidal psammoma bodies.

ADDITIONAL PATHOLOGIC FINDINGS:

Lymphocytic thyroiditis.

NOTE: This case was shown at the
attendance).

(Dr. in

Source: NCI Genomic Data Commons file 4a861fc0-7c79-4184-add5-aba5781939a6 (TCGA-ET-A3BX.D97547B9-7C17-432E-850A-1BB3456F74B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).